CCDI case PBCIGF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/e56a9959-002f-48cb-bc3c-881d675195ed

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 2.5 years (917 days).

Biospecimens (3 samples)
- Sample 0DSYE6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DSYED, 0DSYEM (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
